Somatic mutation profile of tumor specimen ALCH-AEO0-TTP1-A (aliquot ALCH-AEO0-TTP1-A-1-0-D-A612-36) from ALCHEMIST case ALCH-AEO0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.2 years (24,178 days).
Specimen ALCH-AEO0-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8e148ba-7643-4a71-a5d1-0388fc6cbf95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEO0-NB1-A (Blood Derived Normal), aliquot ALCH-AEO0-NB1-A-1-0-D-A612-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e42c42d-871f-45da-aa8c-b0d12b1adde7

The open-access MAF lists 488 somatic variants for this specimen: 337 protein-altering or splice-affecting, 100 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 280, Silent 100, Intron 26, Nonsense Mutation 22, Frame Shift Del 12, Splice Site 12, RNA 9, 3'UTR 8, Splice Region 7, 5'UTR 5, Frame Shift Ins 4, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 338/826 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RYR1 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 38/729 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs193922766, CM023445, CM077625, COSV62103608; ClinVar: pathogenic / not provided; called by muse, mutect2
- STK11 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM012193, CM067471, COSV58820785; called by muse, mutect2, varscan2
- TP53 | c.839G>T p.R280I | Missense Mutation (SNP) | VAF 257/640 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADAM12 | c.2129C>A p.T710N | Missense Mutation (SNP) | VAF 153/466 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV100899955; called by muse, mutect2, varscan2
- ADAMTSL3 | c.205C>A p.R69S | Missense Mutation (SNP) | VAF 59/464 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV99721709; called by muse, mutect2, varscan2
- AGBL5 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 39/293 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs765762435; called by muse, mutect2, varscan2
- ASTN1 | c.2363C>T p.P788L | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as rs748622490; called by muse, mutect2, varscan2
- ATRX | c.4048G>T p.G1350* | Nonsense Mutation (SNP) | VAF 158/564 reads (28%) | catalogued as COSV64883574; called by muse, mutect2, varscan2
- BBS9 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 64/348 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764906719; called by muse, varscan2
- BRDT | c.1751-2A>T p.X584_splice | Splice Site (SNP) | VAF 52/427 reads (12%) | catalogued as rs777827911; called by muse, varscan2
- CABP7 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1468265241, COSV53363450; called by muse, mutect2
- CCDC102B | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 132/564 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60152813; called by muse, mutect2, varscan2
- CDKN2B | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 19/264 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs371415045; called by muse, mutect2
- CDO1 | c.227G>T p.C76F | Missense Mutation (SNP) | VAF 51/361 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs140378688; called by muse, mutect2, varscan2
- CEBPZ | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 97/577 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs558130949; called by muse, mutect2, varscan2
- CES5A | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1218622860; called by muse, mutect2, varscan2
- CHRNA4 | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV64721108; called by muse, varscan2
- CLPTM1 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 50/407 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.121); catalogued as rs1243025738; called by muse, mutect2, varscan2
- COL4A5 | c.3706C>G p.P1236A | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.672); catalogued as rs1416079536, CX107380, COSV60360509; called by muse, mutect2, varscan2
- CRYGD | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 84/540 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs781349703; called by muse, mutect2, varscan2
- CTNNA2 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs751754914, COSV100559548; called by muse, mutect2, varscan2
- CYP17A1 | c.316T>A p.S106T | Missense Mutation (SNP) | VAF 133/417 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.359); catalogued as CM910104; called by muse, mutect2, varscan2
- CYTIP | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV99938917; called by muse, mutect2, varscan2
- DCAF8L1 | c.750C>A p.N250K | Missense Mutation (SNP) | VAF 29/332 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.601); catalogued as COSV71595466; called by muse, mutect2
- DEFB112 | c.179C>A p.T60K | Missense Mutation (SNP) | VAF 130/538 reads (24%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.915); catalogued as COSV59182927; called by muse, mutect2, varscan2
- DHX30 | c.610G>A p.V204I (on ENST00000445061 / NM_138615.3; = p.V165I on NM_014966.3) | Missense Mutation (SNP) | VAF 54/586 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.145); catalogued as rs1297206974; called by muse, mutect2
- DMD | c.9928C>G p.Q3310E | Missense Mutation (SNP) | VAF 52/453 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM050583; called by muse, varscan2
- ERICH3 | c.3923C>A p.A1308E | Missense Mutation (SNP) | VAF 81/368 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs138615520, COSV58603156, COSV58612337; called by muse, mutect2, varscan2
- FAM170B | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs780131272; called by muse, mutect2
- FRRS1 | c.363dup p.K122* | Frame Shift Ins (INS) | VAF 57/405 reads (14%) | catalogued as COSV54921014; called by mutect2, pindel, varscan2
- GABRA5 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 49/506 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59481027; called by muse, mutect2
- GPR149 | c.1842T>A p.S614R | Missense Mutation (SNP) | VAF 106/228 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs375515016; called by muse, mutect2, varscan2
- GRIK2 | c.832G>T p.G278W | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100027784; called by muse, mutect2, varscan2
- HCN1 | c.2307G>C p.K769N | Missense Mutation (SNP) | VAF 115/377 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.105); catalogued as COSV57514045; called by muse, varscan2
- HMCN2 | c.4624G>T p.A1542S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.263); catalogued as rs1351657140; called by muse, varscan2
- HTR1A | c.668G>T p.R223L | Missense Mutation (SNP) | VAF 245/815 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV60500417, COSV60500551; called by muse, mutect2, varscan2
- IL7R | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 157/536 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.597); catalogued as COSV57412909; called by muse, mutect2, varscan2
- ITGAX | c.2705+1G>A p.X902_splice | Splice Site (SNP) | VAF 104/252 reads (41%) | catalogued as rs757366589; called by muse, mutect2, varscan2
- ITSN2 | c.2901G>T p.L967F | Missense Mutation (SNP) | VAF 72/463 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.07); catalogued as rs1231829614; called by muse, mutect2, varscan2
- KHDRBS2 | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 40/464 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as rs377093981; called by muse, mutect2
- KIAA0100 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 22/390 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs935669562; called by muse, mutect2
- LRP1B | c.2971G>C p.D991H | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV67269714; called by muse, mutect2
- MAN2C1 | c.2658-6C>T | Splice Region (SNP) | VAF 12/180 reads (7%) | catalogued as rs1371834392; called by muse, mutect2
- MAP3K15 | c.1190A>T p.Q397L | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58833133; called by muse, mutect2, varscan2
- MCIDAS | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 97/323 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1347065948; called by muse, mutect2, varscan2
- MEAF6 | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV56162605, COSV56163847; called by muse, mutect2, varscan2
- MEGF10 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 77/370 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs201832505; called by muse, mutect2, varscan2
- MRGPRF | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 326/528 reads (62%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.558); catalogued as COSV57996223; called by muse, mutect2, varscan2
- MTMR8 | c.511G>T p.V171F | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100878290; called by muse, mutect2, varscan2
- MYO3A | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 44/636 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs928696768, COSV56346989; called by muse, mutect2
- NCAN | c.1790C>A p.P597Q | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.694); catalogued as COSV53057561; called by muse, mutect2, varscan2
- NLGN4X | c.1591G>C p.A531P | Missense Mutation (SNP) | VAF 170/579 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52022843; called by muse, varscan2
- NLGN4X | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 35/302 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52029188; called by muse, mutect2, varscan2
- NLRP12 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 177/680 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs141436635; ClinVar: likely benign; called by muse, mutect2, varscan2
- NLRP5 | c.2887C>A p.L963M | Missense Mutation (SNP) | VAF 84/395 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV66768081; called by muse, mutect2, varscan2
- NOBOX | c.487del p.R163Afs*11 | Frame Shift Del (DEL) | VAF 17/86 reads (20%) | catalogued as rs754069719; called by mutect2, pindel
- OLIG3 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs747409902; called by muse, mutect2, varscan2
- OR2T11 | c.126G>T p.M42I | Missense Mutation (SNP) | VAF 201/750 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV58186126; called by muse, mutect2, varscan2
- PARD3 | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 126/344 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60754926; called by muse, mutect2, varscan2
- PCDHB5 | c.841C>G p.L281V | Missense Mutation (SNP) | VAF 56/331 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); catalogued as rs782616677; called by muse, mutect2, varscan2
- PCDHGB7 | c.2240C>T p.T747M | Missense Mutation (SNP) | VAF 23/345 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750814136; called by muse, mutect2
- PDE10A | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 22/293 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63101781; called by muse, mutect2
- PDYN | c.751C>G p.L251V | Missense Mutation (SNP) | VAF 136/476 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs761506243, COSV54100713; called by muse, mutect2, varscan2
- PGLYRP3 | c.54G>T p.W18C | Missense Mutation (SNP) | VAF 78/465 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51949553; called by muse, mutect2, varscan2
- PODN | c.1387C>T p.R463C (on ENST00000395871; = p.R415C on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/272 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs780959803, COSV100439882, COSV57014401; called by muse, mutect2, varscan2
- POTEE | c.119A>G p.K40R | Missense Mutation (SNP) | VAF 72/1222 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.292); catalogued as rs1388011888; called by muse, mutect2
- POU3F4 | c.94C>A p.R32S | Missense Mutation (SNP) | VAF 38/308 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV104427747; called by muse, mutect2, varscan2
- PPP1R3A | c.1751C>A p.S584* | Nonsense Mutation (SNP) | VAF 99/422 reads (23%) | catalogued as COSV52876312; called by muse, mutect2, varscan2
- PSMC2 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs758549858, COSV53008364; called by muse, mutect2, varscan2
- PTPN11 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 209/532 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61010026, COSV61011574; called by muse, mutect2, varscan2
- QRICH2 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 145/535 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.276); catalogued as rs1290978486; called by muse, mutect2, varscan2
- RADIL | c.2659C>T p.R887C | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs766194793; called by muse, mutect2, varscan2
- RAPGEF6 | c.3997C>G p.L1333V | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV99726878; called by muse, mutect2
- RCL1 | c.718G>T p.G240C | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101099372, COSV67753923; called by muse, mutect2, varscan2
- RTL1 | c.3745C>A p.H1249N | Missense Mutation (SNP) | VAF 84/192 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV66017399; called by muse, mutect2, varscan2
- RYR1 | c.6407G>A p.R2136H | Missense Mutation (SNP) | VAF 38/448 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs530885842, COSV62103633; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- SALL4 | c.2464C>T p.R822W | Missense Mutation (SNP) | VAF 91/162 reads (56%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as COSV53855928; called by muse, varscan2
- SCN2A | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 136/539 reads (25%) | catalogued as rs1553567936; called by muse, mutect2, varscan2
- SCN9A | c.2230C>T p.P744S (on ENST00000303354; = p.P733S on NM_002977.3) | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs868367454, COSV57604206; called by muse, varscan2
- SERPINA10 | c.821A>C p.K274T | Missense Mutation (SNP) | VAF 61/470 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.665); catalogued as rs748068345, COSV56229376; called by muse, mutect2, varscan2
- SERPINB11 | c.62G>A p.S21N | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs964077675, COSV66956451; called by muse, mutect2, varscan2
- SETBP1 | c.4242G>C p.M1414I | Missense Mutation (SNP) | VAF 113/622 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV56332741; called by muse, mutect2, varscan2
- SFXN5 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 71/282 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as rs768905463, COSV99728934; called by muse, mutect2, varscan2
- SH3TC2 | c.3699C>A p.Y1233* | Nonsense Mutation (SNP) | VAF 124/748 reads (17%) | catalogued as COSV60464818; called by muse, mutect2, varscan2
- SLC13A1 | c.1748C>A p.P583H | Missense Mutation (SNP) | VAF 51/254 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99521339; called by muse, mutect2, varscan2
- SNAI1 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 101/184 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317927184; called by muse, mutect2, varscan2
- SORCS3 | c.1175G>A p.S392N | Missense Mutation (SNP) | VAF 44/365 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63820258; called by muse, mutect2, varscan2
- SPATA31A6 | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 186/376 reads (49%) | catalogued as COSV60534229; called by mutect2, varscan2
- SPATA31D3 | c.2620G>C p.A874P | Missense Mutation (SNP) | VAF 120/483 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100500912; called by muse, mutect2, varscan2
- SPN | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as rs1190363450; called by muse, mutect2
- SPO11 | c.1062G>T p.W354C | Missense Mutation (SNP) | VAF 74/373 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100625812; called by muse, mutect2, varscan2
- SS18 | c.331G>T p.G111C | Missense Mutation (SNP) | VAF 63/333 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.019); catalogued as rs1356901674; called by muse, mutect2, varscan2
- TG | c.6008A>G p.D2003G | Missense Mutation (SNP) | VAF 1485/2267 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as rs1467472504; called by muse, mutect2, varscan2
- TTN | c.49254C>A p.H16418Q (on ENST00000591111; = p.H8994Q on NM_003319.4) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | PolyPhen benign (0.024); catalogued as rs772133203, COSV100592179, COSV59979901; called by muse, mutect2, varscan2
- UBE2O | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 74/267 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV60061840; called by muse, mutect2, varscan2
- VTCN1 | c.98-1G>A p.X33_splice | Splice Site (SNP) | VAF 96/481 reads (20%) | catalogued as COSV60223017; called by muse, mutect2, varscan2
- WNT5A | c.220G>C p.G74R | Missense Mutation (SNP) | VAF 66/267 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1218199102; called by muse, mutect2, varscan2
- XIAP | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 29/391 reads (7%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.83); catalogued as rs745844064; called by muse, mutect2
- XIRP2 | c.5824G>T p.A1942S (on ENST00000628543; = p.A2117S on NM_152381.6) | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs1316494310; called by muse, mutect2, varscan2
- XIRP2 | c.8903A>T p.Q2968L (on ENST00000628543; = p.Q3143L on NM_152381.6) | Missense Mutation (SNP) | VAF 59/297 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV54722635; called by muse, mutect2, varscan2
- XYLT1 | c.1106G>T p.R369L | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99761939; called by muse, mutect2, varscan2
- ZIC2 | c.1004G>T p.C335F | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM091707, COSV66255517; called by muse, mutect2, varscan2
- ZNF16 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 73/343 reads (21%) | catalogued as COSV52766106; called by muse, mutect2, varscan2
- ZNF536 | c.3239C>A p.A1080D | Missense Mutation (SNP) | VAF 99/431 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.08); catalogued as rs1265477897, COSV62828379; called by muse, mutect2, varscan2
- ZNF845 | c.2090G>T p.G697V | Missense Mutation (SNP) | VAF 83/334 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV72004812; called by muse, mutect2, varscan2
- ABCA8 | c.3312C>T p.V1104= | Splice Region (SNP) | VAF 31/223 reads (14%) | called by muse, mutect2, varscan2
- ABCC6 | c.3434C>A p.P1145H | Missense Mutation (SNP) | VAF 170/472 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ABCG1 | c.1877_1884dup p.C629Tfs*127 | Frame Shift Ins (INS) | VAF 87/460 reads (19%) | called by mutect2, varscan2
- ACADM | c.456G>C p.E152D | Missense Mutation (SNP) | VAF 136/652 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, varscan2
- ACO1 | c.1460T>C p.V487A | Missense Mutation (SNP) | VAF 47/377 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ACTRT1 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ADAM29 | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ADAMTS10 | c.3222G>T p.K1074N | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS20 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- ADNP2 | c.2838C>G p.S946R | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- AHNAK2 | c.15884C>A p.S5295Y | Missense Mutation (SNP) | VAF 139/360 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- AKAIN1 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 68/245 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ALX3 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AMER2 | c.1027C>A p.P343T | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AMPH | c.1663G>A p.G555R | Missense Mutation (SNP) | VAF 66/342 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- ANGPTL3 | c.667C>A p.P223T | Missense Mutation (SNP) | VAF 61/411 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ANGPTL3 | c.668C>A p.P223Q | Missense Mutation (SNP) | VAF 62/410 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- ANK2 | c.2339T>A p.L780Q | Missense Mutation (SNP) | VAF 289/741 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD30B | c.1599G>T p.K533N | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- AP1M1 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 47/131 reads (36%) | called by muse, mutect2, varscan2
- APAF1 | c.2290G>T p.D764Y (on ENST00000551964 / NM_181861.2; = p.D753Y on NM_001160.3) | Missense Mutation (SNP) | VAF 140/401 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APBA2 | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 330/682 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ARHGAP25 | c.1004G>A p.G335E (on ENST00000409202 / NM_001007231.3; = p.G327E on NM_014882.3) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, varscan2
- ASB10 | c.176G>T p.W59L | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- ASPM | c.7112A>T p.N2371I | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ATP9B | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- BCAS1 | c.741G>T p.K247N | Missense Mutation (SNP) | VAF 69/110 reads (63%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- BRCC3 | c.355G>T p.G119C | Missense Mutation (SNP) | VAF 32/402 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BRWD3 | c.210C>G p.D70E | Missense Mutation (SNP) | VAF 50/714 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.208); called by muse, mutect2
- C14orf28 | c.740C>G p.S247C | Missense Mutation (SNP) | VAF 154/412 reads (37%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1B | c.4519A>T p.N1507Y | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNA1F | c.618G>T p.R206S | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CACNA1S | c.1040G>T p.R347M | Missense Mutation (SNP) | VAF 67/360 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CAPS2 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 77/178 reads (43%) | called by muse, mutect2, varscan2
- CARMIL1 | c.2036A>T p.Q679L | Missense Mutation (SNP) | VAF 112/423 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CASC3 | c.990A>T p.E330D | Missense Mutation (SNP) | VAF 143/388 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CCDC27 | c.588G>C p.E196D | Missense Mutation (SNP) | VAF 58/294 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CD40 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH23 | c.3318C>G p.S1106R | Missense Mutation (SNP) | VAF 57/356 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- CDH8 | c.1585C>T p.H529Y | Missense Mutation (SNP) | VAF 105/301 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- CHPF | c.378_379del p.Q127Dfs*66 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by pindel, varscan2
- CHST8 | c.368C>A p.A123E | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CNGB1 | c.2675A>G p.Y892C | Missense Mutation (SNP) | VAF 161/398 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CNTNAP2 | c.939+7G>A | Splice Region (SNP) | VAF 77/481 reads (16%) | called by muse, mutect2, varscan2
- COL15A1 | c.2181del p.P729Qfs*23 | Frame Shift Del (DEL) | VAF 24/110 reads (22%) | called by mutect2, pindel, varscan2
- COL9A1 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 58/413 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CORO7 | c.2627G>C p.R876P | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- CRB2 | c.721G>T p.G241C | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CROT | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CSMD3 | c.7964C>T p.T2655I (on ENST00000297405 / NM_001363185.1; = p.T2551I on NM_052900.3) | Missense Mutation (SNP) | VAF 267/433 reads (62%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CTAGE1 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 100/331 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTSA | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 40/302 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); called by muse, varscan2
- CYLC1 | c.234G>T p.R78S | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.124); called by muse, varscan2
- DDX20 | c.1602A>T p.K534N | Missense Mutation (SNP) | VAF 152/516 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- DDX21 | c.1837G>T p.A613S | Missense Mutation (SNP) | VAF 69/291 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- DIAPH2 | c.440C>A p.A147D | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- DNAH3 | c.4978G>A p.V1660I | Missense Mutation (SNP) | VAF 80/315 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- DNAJC25 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 83/293 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNMBP | c.3263G>C p.S1088T | Missense Mutation (SNP) | VAF 128/352 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOLK | c.1476C>G p.I492M | Missense Mutation (SNP) | VAF 107/922 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- EFCAB6 | c.2621A>T p.N874I | Missense Mutation (SNP) | VAF 111/321 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- EFCAB8 | c.3380G>T p.W1127L | Missense Mutation (SNP) | VAF 100/248 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.017); called by muse, varscan2
- EFCAB8 | c.3381G>T p.W1127C | Missense Mutation (SNP) | VAF 100/248 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.029); called by muse, varscan2
- ELF4 | c.941C>A p.P314H | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- EPB41L3 | c.2662G>T p.G888C | Missense Mutation (SNP) | VAF 21/347 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.235); called by muse, mutect2
- EPHB2 | c.1727A>T p.E576V (on ENST00000400191 / NM_001309193.2; = p.E577V on NM_004442.7) | Missense Mutation (SNP) | VAF 38/458 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2
- ERCC6L2 | c.*1506C>T | Splice Region (SNP) | VAF 26/244 reads (11%) | called by muse, mutect2, varscan2
- FAM110B | c.1058A>G p.K353R | Missense Mutation (SNP) | VAF 92/534 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAXDC2 | c.281T>A p.F94Y | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FBN2 | c.7652T>A p.L2551Q | Missense Mutation (SNP) | VAF 99/492 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- FBXO5 | c.382A>T p.N128Y | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2
- FLNC | c.6851G>A p.G2284E | Missense Mutation (SNP) | VAF 84/319 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMN2 | c.3560C>A p.P1187Q | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FOXD2 | c.444_447del p.T149* | Frame Shift Del (DEL) | VAF 101/422 reads (24%) | called by mutect2, pindel, varscan2
- FSHR | c.49G>T p.G17* | Nonsense Mutation (SNP) | VAF 585/1043 reads (56%) | called by muse, mutect2, varscan2
- GABRA5 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 103/290 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- GABRG3 | c.184C>A p.L62M | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- GCK | c.457C>G p.P153A | Missense Mutation (SNP) | VAF 195/581 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GCOM1 | c.910A>G p.R304G | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- GFY | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GLYATL1 | c.116C>A p.P39H (on ENST00000317391 / NM_001354699.1; = p.P70H on NM_080661.4) | Missense Mutation (SNP) | VAF 124/585 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR149 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 120/226 reads (53%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR85 | c.911C>A p.A304D | Missense Mutation (SNP) | VAF 80/299 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- GRAMD1B | c.1685G>T p.R562L | Missense Mutation (SNP) | VAF 79/251 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GSPT2 | c.1699G>T p.E567* | Nonsense Mutation (SNP) | VAF 16/320 reads (5%) | called by muse, mutect2
- HAPLN1 | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 180/374 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- HCN1 | c.2431T>A p.S811T | Missense Mutation (SNP) | VAF 72/242 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); called by muse, varscan2
- HCRTR2 | c.582C>G p.S194R | Missense Mutation (SNP) | VAF 209/711 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- HECTD2 | c.2319dup p.G774Wfs*3 | Frame Shift Ins (INS) | VAF 29/145 reads (20%) | called by mutect2, pindel, varscan2
- HEPACAM | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- HNRNPA1 | c.871A>G p.N291D | Missense Mutation (SNP) | VAF 153/601 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- IDH1 | c.1238A>T p.K413I | Missense Mutation (SNP) | VAF 58/296 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); called by muse, varscan2
- IFI16 | c.1252A>T p.S418C | Missense Mutation (SNP) | VAF 72/276 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.178C>A p.H60N | Missense Mutation (SNP) | VAF 197/1128 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV3-11 | c.17G>T p.S6I | Missense Mutation (SNP) | VAF 54/582 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.03); called by muse, mutect2
- IGLV3-32 | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- IL17F | c.77G>T p.S26I | Missense Mutation (SNP) | VAF 211/803 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ING4 | c.722G>T p.R241L (on ENST00000396807 / NM_001127582.2; = p.R240L on NM_016162.4) | Missense Mutation (SNP) | VAF 88/358 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- INSL6 | c.341C>A p.P114H | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- INTS6L | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 54/372 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- INTS6L | c.1325G>A p.G442E | Missense Mutation (SNP) | VAF 56/378 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ITGA1 | c.2344A>T p.T782S | Missense Mutation (SNP) | VAF 72/436 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ITGA2B | c.1657C>A p.L553M | Missense Mutation (SNP) | VAF 78/299 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ITGAX | c.2227C>T p.L743F | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- ITPKB | c.1136G>T p.C379F | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ITPRID1 | c.1821C>A p.D607E | Missense Mutation (SNP) | VAF 82/462 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- KBTBD8 | c.1525T>A p.W509R | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNH8 | c.598C>A p.P200T | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- KRTAP13-3 | c.307G>C p.G103R | Missense Mutation (SNP) | VAF 53/423 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- LAMA4 | c.4133+1G>T p.X1378_splice (on ENST00000230538 / NM_001105206.3; = p.X1371_splice on NM_002290.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 50/216 reads (23%) | called by muse, varscan2
- LEXM | c.1142C>A p.S381Y | Missense Mutation (SNP) | VAF 61/265 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- LILRA2 | c.352+1G>T p.X118_splice | Splice Site (SNP) | VAF 31/112 reads (28%) | called by muse, mutect2, varscan2
- LRP1 | c.1285G>T p.D429Y | Missense Mutation (SNP) | VAF 116/442 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- LRRC7 | c.3776G>T p.R1259M (on ENST00000651989 / NM_001370785.2; = p.R1226M on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/263 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRD1 | c.242A>T p.Q81L | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2
- LRRIQ1 | c.4276G>T p.E1426* | Nonsense Mutation (SNP) | VAF 57/163 reads (35%) | called by muse, mutect2, varscan2
- LTF | c.1131T>A p.C377* | Nonsense Mutation (SNP) | VAF 52/187 reads (28%) | called by muse, mutect2, varscan2
- MAGEB5 | c.580T>A p.C194S | Missense Mutation (SNP) | VAF 103/259 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAGEC3 | c.1429G>T p.V477F | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); called by muse, mutect2
- MAGEE1 | c.348del p.P117Lfs*12 | Frame Shift Del (DEL) | VAF 45/183 reads (25%) | called by mutect2, pindel, varscan2
- MAGT1 | c.299T>C p.L100P (on ENST00000618282 / NM_001367916.1; = p.L132P on NM_032121.5) | Missense Mutation (SNP) | VAF 48/508 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- MCF2 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 24/314 reads (8%) | called by muse, mutect2
- MCF2L | c.1086+1G>T p.X362_splice (on ENST00000375608; = p.X330_splice on NM_024979.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- MID1 | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 70/798 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.1); called by muse, mutect2
- MKRN3 | c.327C>A p.C109* | Nonsense Mutation (SNP) | VAF 84/295 reads (28%) | called by muse, mutect2, varscan2
- MMRN1 | c.2422G>A p.G808S | Missense Mutation (SNP) | VAF 76/189 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MPEG1 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 41/630 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2
- MS4A15 | c.395C>A p.T132N (on ENST00000405633 / NM_001098835.2; = p.T39N on NM_152717.3) | Missense Mutation (SNP) | VAF 78/262 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- MS4A2 | c.115T>A p.L39M | Missense Mutation (SNP) | VAF 160/592 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- MUC16 | c.5435G>T p.R1812I | Missense Mutation (SNP) | VAF 104/369 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- MYCBP2 | c.1714A>T p.S572C (on ENST00000357337; = p.S610C on NM_015057.5) | Missense Mutation (SNP) | VAF 86/225 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- MYO18B | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 28/271 reads (10%) | called by muse, mutect2
- MYO1F | c.282C>A p.Y94* | Nonsense Mutation (SNP) | VAF 113/345 reads (33%) | called by muse, mutect2, varscan2
- MYOF | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 40/302 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- NAP1L3 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 45/373 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFXL1 | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 75/316 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NHLH1 | c.151G>T p.G51* | Nonsense Mutation (SNP) | VAF 64/228 reads (28%) | called by muse, mutect2, varscan2
- NOG | c.242C>A p.T81N | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- NOX1 | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 34/306 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.042); called by muse, mutect2
- NTNG2 | c.227T>A p.L76Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2F1 | c.381_382del p.C127* | Frame Shift Del (DEL) | VAF 35/236 reads (15%) | called by pindel, varscan2*
- OR2H2 | c.208T>A p.C70S | Missense Mutation (SNP) | VAF 67/233 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR4A47 | c.574G>C p.A192P | Missense Mutation (SNP) | VAF 90/204 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- OR4Q3 | c.763G>T p.V255L | Missense Mutation (SNP) | VAF 170/855 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OSGIN2 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- OTOL1 | c.455-1G>T p.X152_splice | Splice Site (SNP) | VAF 180/371 reads (49%) | called by muse, mutect2, varscan2
- OTOL1 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 186/378 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P2RY4 | c.65A>T p.E22V | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- PAK5 | c.1541T>A p.L514H | Missense Mutation (SNP) | VAF 105/528 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDH17 | c.1441G>A p.V481M | Missense Mutation (SNP) | VAF 34/413 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PCDHB3 | c.2248C>G p.Q750E | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.46); called by muse, mutect2
- PCDHB5 | c.1525A>T p.N509Y | Missense Mutation (SNP) | VAF 160/884 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PCNX2 | c.3891G>T p.W1297C | Missense Mutation (SNP) | VAF 154/445 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PFKFB1 | c.670G>C p.G224R | Missense Mutation (SNP) | VAF 23/278 reads (8%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- PHF20L1 | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 159/926 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- PHLPP1 | c.4122G>T p.K1374N | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- PLEC | c.3509T>C p.V1170A (on ENST00000322810 / NM_201380.4; = p.V1060A on NM_000445.5) | Missense Mutation (SNP) | VAF 23/382 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.108); called by muse, mutect2
- PLEKHG1 | c.2542A>G p.K848E | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- PLPP4 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 40/210 reads (19%) | called by muse, varscan2
- PLPP7 | c.708C>A p.H236Q | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- PLPPR4 | c.1876C>A p.H626N | Missense Mutation (SNP) | VAF 88/524 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNB3 | c.2341C>A p.L781I | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, mutect2
- PML | c.411C>G p.D137E | Missense Mutation (SNP) | VAF 79/465 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- POU6F2 | c.391C>A p.L131I | Missense Mutation (SNP) | VAF 190/690 reads (28%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PPCDC | c.58G>C p.V20L | Missense Mutation (SNP) | VAF 62/523 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PPP2R2D | c.206G>T p.S69I | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, varscan2
- PPP6R1 | c.1161G>T p.L387= | Splice Region (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- PRKAA2 | c.1222A>T p.S408C | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PSMD11 | c.1166A>T p.D389V | Missense Mutation (SNP) | VAF 197/545 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- PTCH2 | c.1190G>T p.R397L | Missense Mutation (SNP) | VAF 76/346 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTGIR | c.365G>A p.S122N | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PTGS1 | c.530C>G p.A177G | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTPA | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 23/183 reads (13%) | called by muse, mutect2, varscan2
- PUM2 | c.326_332del p.S109Lfs*46 | Frame Shift Del (DEL) | VAF 48/253 reads (19%) | called by mutect2, pindel, varscan2
- PWWP3B | c.805C>A p.P269T | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RASD2 | c.17C>A p.S6Y | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- RBP7 | c.93_94del p.K32Nfs*12 | Frame Shift Del (DEL) | VAF 52/319 reads (16%) | called by mutect2, pindel
- RCC2 | c.1481C>A p.S494* | Nonsense Mutation (SNP) | VAF 70/325 reads (22%) | called by muse, mutect2, varscan2
- RGSL1 | c.1280dup p.L427Ffs*4 | Frame Shift Ins (INS) | VAF 144/536 reads (27%) | called by mutect2, pindel, varscan2
- RHAG | c.88C>A p.Q30K | Missense Mutation (SNP) | VAF 166/718 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- RHOBTB3 | c.271G>T p.G91W | Missense Mutation (SNP) | VAF 72/286 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- RNASE11 | c.389G>T p.R130M | Missense Mutation (SNP) | VAF 126/550 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.327); called by muse, mutect2
- RNF112 | c.971A>T p.N324I | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- RNF213 | c.2493C>A p.Y831* | Nonsense Mutation (SNP) | VAF 377/1036 reads (36%) | called by muse, mutect2, varscan2
- ROCK2 | c.154T>G p.S52A | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SCN4A | c.4018-1del p.X1340_splice | Splice Site (DEL) | VAF 12/64 reads (19%) | called by mutect2, pindel
- SDR42E1 | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPINB13 | c.331del p.E111Kfs*11 | Frame Shift Del (DEL) | VAF 16/149 reads (11%) | called by mutect2, pindel, varscan2
- SERPINB5 | c.681C>A p.S227R | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SERPING1 | c.970A>T p.M324L | Missense Mutation (SNP) | VAF 172/766 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- SGO1 | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC9A3 | c.1356G>T p.Q452H | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SMCO3 | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 121/416 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMOC2 | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMPD1 | c.1487-2A>T p.X496_splice | Splice Site (SNP) | VAF 34/384 reads (9%) | called by muse, mutect2
- SYBU | c.336del p.R113Efs*28 (on ENST00000276646 / NM_001099754.2; = p.R112Efs*28 on NM_017786.6) | Frame Shift Del (DEL) | VAF 362/820 reads (44%) | called by mutect2, pindel, varscan2
- SYNE1 | c.4461+8G>T | Splice Region (SNP) | VAF 46/282 reads (16%) | called by mutect2, varscan2
- SYNGR4 | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 133/392 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TBC1D13 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 9/103 reads (9%) | called by muse, mutect2
- TBC1D24 | c.639G>T p.Q213H | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2
- TBX4 | c.1292T>C p.V431A | Missense Mutation (SNP) | VAF 232/750 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- TG | c.6007G>T p.D2003Y | Missense Mutation (SNP) | VAF 1476/2253 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- THRAP3 | c.2465C>G p.P822R | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- THSD7B | c.2327G>A p.G776D | Missense Mutation (SNP) | VAF 104/644 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TLE1 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- TMPRSS15 | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- TNNT2 | c.234-1G>T p.X78_splice | Splice Site (SNP) | VAF 149/498 reads (30%) | called by muse, mutect2, varscan2
- TOGARAM2 | c.1310C>A p.P437H | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIO | c.9021A>C p.L3007F | Missense Mutation (SNP) | VAF 37/752 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- TSHR | c.615-3T>C | Splice Region (SNP) | VAF 131/388 reads (34%) | called by muse, mutect2, varscan2
- TTLL10 | c.536G>T p.W179L (on ENST00000379289 / NM_001130045.2; = p.W106L on NM_153254.3) | Missense Mutation (SNP) | VAF 55/259 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- UBQLN3 | c.909del p.N304Tfs*37 | Frame Shift Del (DEL) | VAF 132/366 reads (36%) | called by mutect2, pindel, varscan2
- USH2A | c.6016A>T p.S2006C | Missense Mutation (SNP) | VAF 188/622 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- USP4 | c.1129-1G>T p.X377_splice | Splice Site (SNP) | VAF 30/133 reads (23%) | called by muse, mutect2, varscan2
- USP7 | c.1426A>C p.K476Q | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2
- WDFY4 | c.2247del p.S751Pfs*34 | Frame Shift Del (DEL) | VAF 58/200 reads (29%) | called by mutect2, pindel, varscan2
- WDR86 | c.851A>T p.H284L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.289); called by muse, varscan2
- XKR4 | c.807-1G>T p.X269_splice | Splice Site (SNP) | VAF 64/480 reads (13%) | called by muse, mutect2, varscan2
- XPNPEP2 | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ZBTB2 | c.43A>G p.N15D | Missense Mutation (SNP) | VAF 44/235 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZFP91 | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 251/1103 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- ZMYM3 | c.2502G>T p.M834I | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2
- ZNF117 | c.34G>T p.V12F | Missense Mutation (SNP) | VAF 98/336 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- ZNF407 | c.5818C>G p.Q1940E | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2
- ZNF467 | c.987G>T p.R329S | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF662 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 129/432 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF676 | c.704G>C p.G235A (on ENST00000650058; = p.G203A on NM_001001411.3) | Missense Mutation (SNP) | VAF 64/303 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF729 | c.3251C>T p.A1084V | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.65); called by muse, mutect2
- ZNF880 | c.209G>C p.S70T | Missense Mutation (SNP) | VAF 62/384 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZNF91 | c.3250G>T p.G1084C | Missense Mutation (SNP) | VAF 70/376 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZYG11B | c.850G>T p.V284F | Missense Mutation (SNP) | VAF 60/285 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ACBD3 | c.117G>T p.L39= | Silent (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- ACTL8 | c.855C>A p.I285= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV64862585; called by muse, mutect2, varscan2
- ADAMTS12 | c.4555A>C p.R1519= | Silent (SNP) | VAF 122/393 reads (31%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.2223G>T p.L741= | Silent (SNP) | VAF 155/598 reads (26%) | catalogued as COSV61256866; called by muse, mutect2, varscan2
- AFF3 | c.2634G>A p.S878= | Silent (SNP) | VAF 38/581 reads (7%) | catalogued as rs537794744, COSV57865946; called by muse, mutect2
- ALDH6A1 | c.36C>T p.A12= | Silent (SNP) | VAF 227/514 reads (44%) | called by muse, mutect2, varscan2
- AMOT | c.1884G>T p.R628= (on ENST00000371959 / NM_001113490.1; = p.R219= on NM_133265.3) | Silent (SNP) | VAF 28/366 reads (8%) | called by muse, mutect2
- AMPH | c.1872C>A p.L624= | Silent (SNP) | VAF 79/260 reads (30%) | called by muse, mutect2, varscan2
- ANGPT1 | c.1302C>T p.N434= | Silent (SNP) | VAF 152/254 reads (60%) | called by muse, mutect2, varscan2
- ANKH | c.138C>T p.V46= | Silent (SNP) | VAF 68/971 reads (7%) | catalogued as rs760311904; called by muse, mutect2
- APOE | c.606G>T p.L202= | Silent (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- BAHCC1 | c.936G>T p.T312= | Silent (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- BDP1 | c.6474A>T p.T2158= | Silent (SNP) | VAF 70/623 reads (11%) | called by muse, mutect2, varscan2
- CAPN14 | c.63G>T p.A21= | Silent (SNP) | VAF 445/862 reads (52%) | catalogued as rs768792436, COSV67290894; called by muse, mutect2, varscan2
- CASQ2 | c.579C>T p.I193= | Silent (SNP) | VAF 74/388 reads (19%) | called by muse, mutect2, varscan2
- CD300LB | c.286C>A p.R96= | Silent (SNP) | VAF 146/426 reads (34%) | called by muse, varscan2
- CD79B | c.537G>T p.L179= | Silent (SNP) | VAF 214/688 reads (31%) | called by mutect2, varscan2
- CHD5 | c.5658C>T p.P1886= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs774782723; called by muse, mutect2, varscan2
- CMYA5 | c.11430C>A p.R3810= | Silent (SNP) | VAF 66/190 reads (35%) | called by muse, mutect2, varscan2
- COL4A2 | c.3486G>C p.S1162= | Silent (SNP) | VAF 42/130 reads (32%) | called by muse, varscan2
- CPA1 | c.528G>T p.T176= | Silent (SNP) | VAF 73/280 reads (26%) | called by muse, mutect2, varscan2
- CPLANE2 | c.657C>T p.D219= | Silent (SNP) | VAF 28/379 reads (7%) | catalogued as rs771994117, COSV65056879; called by muse, mutect2
- CRK | c.558C>T p.Y186= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as rs1208010282, COSV56031407; called by muse, mutect2
- CRYGD | c.351C>T p.R117= | Silent (SNP) | VAF 85/544 reads (16%) | called by muse, mutect2, varscan2
- CYSLTR1 | c.132G>T p.V44= | Silent (SNP) | VAF 22/294 reads (7%) | called by muse, mutect2
- DNAH17 | c.10506C>A p.G3502= | Silent (SNP) | VAF 20/496 reads (4%) | called by muse, mutect2
- ERCC4 | c.360T>A p.T120= | Silent (SNP) | VAF 32/368 reads (9%) | catalogued as COSV100318831; called by muse, mutect2
- ESPNL | c.1866C>A p.T622= | Silent (SNP) | VAF 50/190 reads (26%) | catalogued as COSV100547486; called by muse, mutect2, varscan2
- FAM50A | c.645C>A p.V215= | Silent (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- FRMPD1 | c.477G>T p.V159= | Silent (SNP) | VAF 126/520 reads (24%) | called by muse, mutect2, varscan2
- GAL3ST3 | c.510G>C p.P170= | Silent (SNP) | VAF 56/222 reads (25%) | catalogued as COSV61748631; called by muse, mutect2, varscan2
- GCNT1 | c.339C>T p.P113= | Silent (SNP) | VAF 61/296 reads (21%) | catalogued as rs1178573418; called by muse, mutect2, varscan2
- GLUD2 | c.1470G>T p.T490= | Silent (SNP) | VAF 66/716 reads (9%) | called by muse, mutect2
- GNB2 | c.93C>G p.T31= | Silent (SNP) | VAF 32/320 reads (10%) | called by muse, mutect2
- GPR82 | c.825A>G p.L275= | Silent (SNP) | VAF 18/158 reads (11%) | called by muse, mutect2, varscan2
- GPR85 | c.912C>A p.A304= | Silent (SNP) | VAF 82/299 reads (27%) | called by muse, mutect2, varscan2
- GRAMD1B | c.834C>T p.P278= | Silent (SNP) | VAF 62/178 reads (35%) | called by muse, mutect2, varscan2
- GRAMD1B | c.1686G>T p.R562= | Silent (SNP) | VAF 79/250 reads (32%) | called by muse, mutect2, varscan2
- GRIP2 | c.1536C>A p.P512= (on ENST00000619221; = p.P415= on NM_001080423.4) | Silent (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- HRH2 | c.861G>T p.L287= | Silent (SNP) | VAF 95/312 reads (30%) | called by muse, mutect2, varscan2
- HS3ST2 | c.177C>T p.P59= | Silent (SNP) | VAF 108/278 reads (39%) | catalogued as rs1018185091; called by muse, mutect2, varscan2
- HSP90AB1 | c.816C>A p.I272= | Silent (SNP) | VAF 164/538 reads (30%) | called by muse, mutect2, varscan2
- IGLV3-12 | c.282C>T p.S94= | Silent (SNP) | VAF 44/694 reads (6%) | catalogued as rs535793304; called by muse, mutect2
- IL13RA2 | c.321G>T p.T107= | Silent (SNP) | VAF 9/137 reads (7%) | catalogued as COSV54568248; called by muse, mutect2
- IQSEC2 | c.2424G>T p.G808= (on ENST00000642864 / NM_001111125.3; = p.G603= on NM_015075.2) | Silent (SNP) | VAF 25/207 reads (12%) | called by muse, mutect2, varscan2
- JAKMIP3 | c.783C>A p.G261= | Silent (SNP) | VAF 138/455 reads (30%) | called by muse, mutect2, varscan2
- KCNT2 | c.2586A>G p.K862= | Silent (SNP) | VAF 109/607 reads (18%) | called by muse, mutect2, varscan2
- KCTD7 | c.33C>T p.S11= | Silent (SNP) | VAF 27/228 reads (12%) | called by muse, mutect2, varscan2
- KEL | c.1935G>C p.A645= | Silent (SNP) | VAF 148/709 reads (21%) | called by muse, mutect2, varscan2
- KIAA1210 | c.870G>A p.V290= | Silent (SNP) | VAF 105/353 reads (30%) | called by muse, mutect2, varscan2
- KLK8 | c.540C>T p.P180= | Silent (SNP) | VAF 98/432 reads (23%) | called by muse, mutect2, varscan2
- KRT77 | c.279G>T p.G93= | Silent (SNP) | VAF 55/133 reads (41%) | catalogued as COSV59239149; called by muse, mutect2, varscan2
- LRFN5 | c.1764C>A p.S588= | Silent (SNP) | VAF 196/1904 reads (10%) | catalogued as COSV53259297; called by muse, mutect2
- LRRC59 | c.642G>A p.E214= | Silent (SNP) | VAF 132/362 reads (36%) | catalogued as rs368970733; called by muse, mutect2, varscan2
- MACF1 | c.16479C>T p.I5493= (on ENST00000372915; = p.I3426= on NM_012090.5) | Silent (SNP) | VAF 65/235 reads (28%) | called by muse, mutect2, varscan2
- MAGEA4 | c.792C>T p.G264= | Silent (SNP) | VAF 59/193 reads (31%) | called by muse, mutect2, varscan2
- MAGEB5 | c.201G>T p.L67= | Silent (SNP) | VAF 24/216 reads (11%) | called by muse, mutect2, varscan2
- MAGEL2 | c.2091C>A p.P697= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100045753; called by muse, mutect2, varscan2
- MBD1 | c.297G>A p.Q99= | Silent (SNP) | VAF 142/717 reads (20%) | called by muse, mutect2, varscan2
- MEGF10 | c.2349G>T p.R783= | Silent (SNP) | VAF 65/226 reads (29%) | called by muse, mutect2, varscan2
- MS4A10 | c.747C>T p.A249= | Silent (SNP) | VAF 76/368 reads (21%) | catalogued as rs1250229839; called by muse, mutect2, varscan2
- MTMR1 | c.456A>T p.G152= | Silent (SNP) | VAF 32/283 reads (11%) | called by muse, mutect2, varscan2
- MYO18B | c.1941G>T p.L647= | Silent (SNP) | VAF 54/119 reads (45%) | called by muse, mutect2, varscan2
- NBAS | c.3087A>T p.A1029= | Silent (SNP) | VAF 52/225 reads (23%) | called by muse, mutect2, varscan2
- NKG7 | c.216C>T p.S72= | Silent (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- NRXN1 | c.1878C>G p.V626= | Silent (SNP) | VAF 19/120 reads (16%) | called by muse, mutect2, varscan2
- OLFML2A | c.1458C>T p.I486= | Silent (SNP) | VAF 44/205 reads (21%) | called by muse, mutect2, varscan2
- OR1E1 | c.439C>T p.L147= | Silent (SNP) | VAF 153/358 reads (43%) | called by muse, mutect2, varscan2
- OR2L2 | c.717C>A p.T239= | Silent (SNP) | VAF 55/239 reads (23%) | catalogued as rs1244231604; called by muse, mutect2, varscan2
- OR4C12 | c.792C>A p.P264= | Silent (SNP) | VAF 117/330 reads (35%) | called by muse, mutect2, varscan2
- OR56A3 | c.93G>C p.L31= | Silent (SNP) | VAF 97/238 reads (41%) | catalogued as rs1197017201, COSV61569094; called by muse, mutect2, varscan2
- OR8K3 | c.45G>T p.T15= | Silent (SNP) | VAF 55/167 reads (33%) | called by muse, mutect2, varscan2
- OR9A4 | c.388C>T p.L130= | Silent (SNP) | VAF 122/484 reads (25%) | called by muse, mutect2, varscan2
- PAM | c.393T>C p.N131= | Silent (SNP) | VAF 50/345 reads (14%) | catalogued as rs201178915; called by muse, mutect2, varscan2
- PCDH17 | c.3189C>A p.A1063= | Silent (SNP) | VAF 73/221 reads (33%) | called by muse, mutect2, varscan2
- PCDHA8 | c.2193G>T p.G731= | Silent (SNP) | VAF 105/390 reads (27%) | catalogued as rs782684639; called by muse, mutect2, varscan2
- PDZRN4 | c.2631G>A p.K877= (on ENST00000402685 / NM_001164595.2; = p.K619= on NM_013377.4) | Silent (SNP) | VAF 166/714 reads (23%) | catalogued as COSV54198009; called by muse, mutect2, varscan2
- PON1 | c.156T>A p.S52= | Silent (SNP) | VAF 180/782 reads (23%) | called by muse, mutect2
- POU3F4 | c.894C>A p.L298= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as COSV64539020; called by muse, mutect2
- PTPRC | c.261G>T p.P87= | Silent (SNP) | VAF 156/777 reads (20%) | catalogued as rs780344153; called by muse, mutect2, varscan2
- PYHIN1 | c.1251A>G p.E417= | Silent (SNP) | VAF 17/358 reads (5%) | called by muse, mutect2
- RAB40AL | c.309G>A p.E103= | Silent (SNP) | VAF 31/502 reads (6%) | called by muse, mutect2
- RBM14 | c.990C>T p.S330= | Silent (SNP) | VAF 83/234 reads (35%) | catalogued as COSV59560632; called by muse, mutect2, varscan2
- RBM26 | c.1917G>A p.R639= (on ENST00000438737 / NM_001366735.2; = p.R636= on NM_022118.5) | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV99935803; called by muse, varscan2
- RORB | c.1218G>T p.V406= (on ENST00000396204 / NM_001365023.1; = p.V395= on NM_006914.4) | Silent (SNP) | VAF 42/138 reads (30%) | called by muse, mutect2, varscan2
- RYR2 | c.11070C>A p.A3690= | Silent (SNP) | VAF 116/435 reads (27%) | catalogued as rs1487119561; called by muse, mutect2, varscan2
- RYR2 | c.12465C>G p.S4155= | Silent (SNP) | VAF 77/217 reads (35%) | called by muse, mutect2, varscan2
- SLITRK1 | c.1038C>T p.S346= | Silent (SNP) | VAF 87/208 reads (42%) | catalogued as COSV100999940, COSV65675746; called by muse, mutect2, varscan2
- SP140L | c.1083G>A p.G361= | Silent (SNP) | VAF 33/315 reads (10%) | called by muse, mutect2, varscan2
- THSD7B | c.2244C>A p.P748= | Silent (SNP) | VAF 65/508 reads (13%) | called by muse, mutect2, varscan2
- TMEM135 | c.651C>T p.P217= | Silent (SNP) | VAF 167/868 reads (19%) | catalogued as rs761199433; called by muse, mutect2, varscan2
- TMEM200A | c.678G>T p.V226= | Silent (SNP) | VAF 28/274 reads (10%) | called by muse, mutect2
- TRPS1 | c.867T>C p.G289= (on ENST00000220888 / NM_001330599.2; = p.G302= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/264 reads (14%) | called by muse, mutect2, varscan2
- UGGT1 | c.1389C>T p.N463= | Silent (SNP) | VAF 150/328 reads (46%) | catalogued as rs757613750, COSV52139160; called by muse, mutect2, varscan2
- UNC79 | c.7662C>A p.V2554= (on ENST00000393151 / NM_001346218.2; = p.V2377= on NM_020818.5) | Silent (SNP) | VAF 41/106 reads (39%) | called by muse, mutect2, varscan2
- VSIG4 | c.336G>T p.T112= | Silent (SNP) | VAF 104/250 reads (42%) | called by muse, mutect2, varscan2
- WDCP | c.306G>C p.T102= | Silent (SNP) | VAF 93/786 reads (12%) | catalogued as COSV54592783; called by muse, mutect2, varscan2
- ZNF335 | c.3015C>T p.P1005= | Silent (SNP) | VAF 48/123 reads (39%) | called by muse, mutect2, varscan2
- ZNF766 | c.465G>T p.G155= | Silent (SNP) | VAF 55/216 reads (25%) | called by muse, mutect2, varscan2
- ZNF835 | c.1458C>T p.S486= | Silent (SNP) | VAF 74/347 reads (21%) | called by muse, mutect2, varscan2
- ABCA11P | n.1023A>T | RNA (SNP) | VAF 199/828 reads (24%) | called by muse, mutect2, varscan2
- ABCB7 | chrX:75156682 G>T | 5'Flank (SNP) | VAF 27/446 reads (6%) | called by muse, mutect2
- AC024940.1 | n.2427G>T | RNA (SNP) | VAF 144/624 reads (23%) | called by muse, mutect2, varscan2
- ADGRB3 | c.2481-675G>C | Intron (SNP) | VAF 17/350 reads (5%) | called by muse, mutect2
- AGBL4 | c.34+28461A>G | Intron (SNP) | VAF 61/234 reads (26%) | called by muse, mutect2
- AJAP1 | c.*5176G>T | 3'UTR (SNP) | VAF 47/210 reads (22%) | called by muse, mutect2, varscan2
- ALG11 | c.*57G>T | 3'UTR (SNP) | VAF 85/215 reads (40%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505740 G>C | 5'Flank (SNP) | VAF 36/375 reads (10%) | called by muse, mutect2
- APOO | c.*30-3334G>C | Intron (SNP) | VAF 61/852 reads (7%) | called by muse, mutect2
- ARFGAP2 | c.265-131C>T | Intron (SNP) | VAF 43/86 reads (50%) | catalogued as rs1342960140; called by muse, mutect2, varscan2
- BX537318.2 | n.333C>A | RNA (SNP) | VAF 13/226 reads (6%) | called by muse, mutect2
- CCDC121 | c.-119+424C>T | Intron (SNP) | VAF 121/911 reads (13%) | catalogued as rs1172875284; called by muse, mutect2, varscan2
- CD300LB | c.443+13G>A | Intron (SNP) | VAF 80/223 reads (36%) | catalogued as rs1314854243; called by muse, mutect2, varscan2
- CORIN | c.2068+141G>C | Intron (SNP) | VAF 75/378 reads (20%) | called by muse, mutect2, varscan2
- DCHS2 | n.4000G>A | RNA (SNP) | VAF 30/390 reads (8%) | called by muse, mutect2
- DCHS2 | n.3426G>T | RNA (SNP) | VAF 169/445 reads (38%) | catalogued as COSV100251742, COSV100251939; called by muse, mutect2, varscan2
- EDN2 | c.*134G>T | 3'UTR (SNP) | VAF 47/185 reads (25%) | called by muse, mutect2, varscan2
- ERG | c.-19G>T | 5'UTR (SNP) | VAF 92/391 reads (24%) | called by muse, mutect2, varscan2
- FAM81B | c.656+3664C>T | Intron (SNP) | VAF 31/746 reads (4%) | catalogued as rs948057267; called by muse, mutect2
- FRMPD4 | c.42-157055G>A | Intron (SNP) | VAF 10/250 reads (4%) | called by muse, mutect2
- GABRB1 | c.240+130C>A | Intron (SNP) | VAF 45/136 reads (33%) | called by muse, mutect2, varscan2
- GNL1 | c.-909A>T | 5'UTR (SNP) | VAF 36/504 reads (7%) | called by muse, mutect2
- LAMB2 | c.5261-11G>T | Intron (SNP) | VAF 100/712 reads (14%) | called by muse, mutect2, varscan2
- LHX3 | c.79+1844G>T | Intron (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- LYRM9 | c.-19+923A>G | Intron (SNP) | VAF 144/450 reads (32%) | catalogued as rs963898489; called by muse, mutect2, varscan2
- MLH1 | chr3:36993511 A>T | 5'Flank (SNP) | VAF 51/463 reads (11%) | called by muse, mutect2, varscan2
- MMD2 | c.609+138G>T | Intron (SNP) | VAF 86/225 reads (38%) | called by muse, mutect2, varscan2
- MPC1 | c.76-90G>T | Intron (SNP) | VAF 32/186 reads (17%) | called by muse, varscan2
- MS4A1 | c.-50G>T | 5'UTR (SNP) | VAF 155/550 reads (28%) | called by muse, mutect2, varscan2
- NCKAP1L | c.735+383G>T | Intron (SNP) | VAF 48/136 reads (35%) | called by muse, mutect2, varscan2
- OR52B1P | n.723T>A | RNA (SNP) | VAF 68/175 reads (39%) | called by muse, mutect2, varscan2
- OXCT1 | c.1420-37G>A | Intron (SNP) | VAF 160/523 reads (31%) | catalogued as rs773576289; called by muse, mutect2, varscan2
- PAXBP1 | c.2334+219G>T | Intron (SNP) | VAF 34/352 reads (10%) | called by muse, mutect2, varscan2
- SERPINA10 | c.*24G>C | 3'UTR (SNP) | VAF 117/326 reads (36%) | called by muse, mutect2, varscan2
- SH2B1 | c.1898-222C>A | Intron (SNP) | VAF 17/211 reads (8%) | catalogued as COSV100450759; called by muse, mutect2
- SLAMF1 | c.*467C>A | 3'UTR (SNP) | VAF 70/392 reads (18%) | called by muse, mutect2, varscan2
- SNORA26 | n.73A>G | RNA (SNP) | VAF 21/347 reads (6%) | called by muse, mutect2
- SRD5A1 | c.294-6807G>T | Intron (SNP) | VAF 101/239 reads (42%) | called by muse, mutect2, varscan2
- SRSF11 | c.338-1649G>T | Intron (SNP) | VAF 70/273 reads (26%) | called by muse, mutect2, varscan2
- SSPOP | n.12188G>T | RNA (SNP) | VAF 14/62 reads (23%) | called by muse, varscan2
- ST8SIA6 | c.*2197C>G | 3'UTR (SNP) | VAF 90/376 reads (24%) | called by muse, mutect2, varscan2
- SVIL2P | n.1829C>A | RNA (SNP) | VAF 134/515 reads (26%) | called by muse, mutect2, varscan2
- TCL1A | c.121-277C>A | Intron (SNP) | VAF 47/129 reads (36%) | called by muse, mutect2, varscan2
- TCN1 | c.*12T>A | 3'UTR (SNP) | VAF 167/605 reads (28%) | called by muse, mutect2, varscan2
- THSD4 | c.1016-70060G>T | Intron (SNP) | VAF 156/617 reads (25%) | called by muse, mutect2, varscan2
- TIAM2 | c.2361+3450T>C | Intron (SNP) | VAF 30/282 reads (11%) | called by muse, mutect2
- TRAPPC3L | c.43-453G>T | Intron (SNP) | VAF 29/306 reads (9%) | called by muse, mutect2
- TRPM3 | c.1154+7639A>T | Intron (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- WDR87 | c.-4G>A | 5'UTR (SNP) | VAF 69/216 reads (32%) | catalogued as rs961575886; called by muse, mutect2, varscan2
- ZNF81 | c.-123C>T | 5'UTR (SNP) | VAF 34/472 reads (7%) | catalogued as rs782493723; called by muse, mutect2
- ZNF99 | c.*807C>G | 3'UTR (SNP) | VAF 68/258 reads (26%) | called by muse, mutect2, varscan2
